CCDI case PBBWUD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/fcd3c01f-019c-4025-9227-26b6bd005ce4

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 16.7 years (6,096 days).

Biospecimens (3 samples)
- Sample 0DKF9K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKF9Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DL6RN: Tissue type: Tumor; Specimen type: Solid Tissue.
